Gene-level copy-number profile of tumor specimen MP2PRT-PAUTCU-TMP1-A from MP2PRT case MP2PRT-PAUTCU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 7.2 years (2,645 days).
Specimen MP2PRT-PAUTCU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a26da874-1b4a-410f-a9e4-1b48305f174b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUTCU-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,271 have no estimate.
https://portal.gdc.cancer.gov/files/ae9e9f2f-030f-4a02-98c8-b7efbec137cd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 191; copy number 2: 45,521; copy number 3: 234; copy number 4: 11,653; copy number 5: 321; copy number 6: 431.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–2): CDKN2A-DT.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 752 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene, copy number 5 (within-gene range 2–5): RSRP1.
- chr1:25,272,393–25,330,445, 2 genes, copy number 5: RHD, SDHDP6.
- chr6:118,452,469–118,454,992, 1 gene, copy number 5: AL589993.1.
- chr14:18,601,045–18,614,561, 2 genes, copy number 6: OR11H12, CR383656.6.
- chr14:21,941,128–22,163,870, 23 genes, copy number 5: TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5.
- chr21:8,680,538–8,680,934, 1 gene, copy number 5: CR381572.2.
- chr21:13,038,160–46,691,226, 722 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 191. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
